Somatic mutation profile of tumor specimen TCGA-DK-A2I6-01A (aliquot TCGA-DK-A2I6-01A-12D-A18F-08) from TCGA case TCGA-DK-A2I6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 81.6 years (29,789 days).
Specimen TCGA-DK-A2I6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb115211-a3c5-4bb9-a014-996c45c30b14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A2I6-10A (Blood Derived Normal), aliquot TCGA-DK-A2I6-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/049b32ae-f4ab-4684-a92d-1cccb7e82520

The open-access MAF lists 324 somatic variants for this specimen: 225 protein-altering or splice-affecting, 90 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 90, Nonsense Mutation 14, Intron 3, In Frame Del 3, RNA 3, Splice Site 2, 5'UTR 2, Frame Shift Del 2, Splice Region 2, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>T p.D1399Y | Missense Mutation (SNP) | VAF 31/94 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 113/120 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54064293; called by muse, mutect2, varscan2
- KDM6A | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | hotspot (GDC flag); catalogued as COSV65037942; called by muse, mutect2, varscan2
- KMT2A | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as rs1555035511, COSV63292737; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as rs770025422, CX1111739, COSV64293089; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.2195A>G p.K732R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54694326; called by muse, mutect2, varscan2
- ABHD16A | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV65451525; called by muse, mutect2, varscan2
- ABHD3 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.661); catalogued as COSV104387606, COSV56676021; called by muse, mutect2, varscan2
- ACTR3 | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs375902041; called by muse, mutect2, varscan2
- AFF4 | c.2801A>G p.D934G | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV54792997; called by muse, mutect2, varscan2
- AGAP2 | c.3047G>A p.R1016Q (on ENST00000547588 / NM_001122772.2; = p.R660Q on NM_014770.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs760586368, COSV57727418; called by muse, mutect2, varscan2
- AK7 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV50870058, COSV50884648; called by muse, mutect2, varscan2
- AKAP6 | c.4815C>A p.S1605R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55208796; called by muse, mutect2, varscan2
- ANGPTL4 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV56844542, COSV56845660; called by muse, mutect2
- ANGPTL4 | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV56844553; called by muse, mutect2
- AOAH | c.457T>G p.S153A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.027); catalogued as COSV51737830; called by muse, mutect2, varscan2
- APBA2 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs142481200; called by muse, mutect2, varscan2
- APTX | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.42); catalogued as COSV58928144; called by muse, mutect2, varscan2
- ARHGEF1 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV61526894; called by muse, mutect2, varscan2
- ARNT2 | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV57583016; called by muse, mutect2, varscan2
- AUNIP | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 38/624 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV65352640; called by muse, mutect2
- AUTS2 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV61390323; called by muse, mutect2, varscan2
- AXIN2 | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as rs145717795, COSV61056492; ClinVar: likely benign; called by muse, mutect2
- B4GALNT3 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs759575390, COSV56751121; called by muse, mutect2, varscan2
- BIRC6 | c.10453G>A p.G3485S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.437); catalogued as rs994269604, COSV70197202; called by muse, mutect2
- BIRC6 | c.10454G>T p.G3485V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.537); catalogued as COSV70197205; called by muse, mutect2
- BMP2K | c.3299C>A p.P1100Q | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV55009024; called by muse, mutect2, varscan2
- BSN | c.7327G>A p.E2443K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772839748, COSV56515073; called by muse, mutect2, varscan2
- CALCRL | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV66474133; called by muse, mutect2, varscan2
- CALD1 | c.2038G>A p.E680K (on ENST00000361675 / NM_033138.4; = p.E425K on NM_004342.7) | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052350216, COSV62646280; called by muse, mutect2, varscan2
- CALHM2 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV53294799; called by muse, mutect2, varscan2
- CAP1 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV61223042; called by muse, mutect2, varscan2
- CBLL1 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV56028453, COSV99755862; called by muse, mutect2, varscan2
- CCDC141 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as COSV55368151; called by muse, mutect2, varscan2
- CCND3 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV57828156; called by muse, mutect2, varscan2
- CCND3 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV65912467; called by muse, mutect2, varscan2
- CD163 | c.3223C>T p.R1075* | Nonsense Mutation (SNP) | VAF 67/144 reads (47%) | catalogued as COSV63138480; called by muse, mutect2, varscan2
- CD63 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1482247479, COSV57676130; called by muse, mutect2, varscan2
- CDH16 | c.1324A>T p.I442F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV55335712; called by muse, mutect2, varscan2
- CDK17 | c.18A>T p.R6S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV54127648; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4712A>T p.H1571L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as COSV62573163; called by muse, mutect2, varscan2
- CMIP | c.1330G>C p.E444Q (on ENST00000537098 / NM_198390.2; = p.E350Q on NM_030629.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.009); catalogued as COSV67697622; called by muse, mutect2, varscan2
- CNIH3 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs746644166, COSV55272731; called by muse, mutect2, varscan2
- CNTNAP5 | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV70473955, COSV70479294; called by muse, mutect2, varscan2
- CRYBG3 | c.8710G>A p.G2904R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369925348; called by muse, mutect2, varscan2
- CSAD | c.464C>G p.S155C (on ENST00000444623 / NM_001244705.2; = p.S182C on NM_015989.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57241845; called by muse, mutect2, varscan2
- CSMD2 | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53894886; called by muse, mutect2
- DCAF17 | c.432A>G p.I144M | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV59829916; called by muse, mutect2, varscan2
- DCK | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV54378015; called by muse, mutect2, varscan2
- DNAH7 | c.6964C>A p.H2322N | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56757274; called by muse, mutect2
- DPYS | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); catalogued as COSV60906791; called by muse, mutect2, varscan2
- DST | c.11773T>A p.L3925I (on ENST00000361203 / NM_001374722.1; = p.L1513I on NM_015548.5) | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV55004978; called by muse, mutect2, varscan2
- DZIP3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV64311550; called by muse, mutect2, varscan2
- ELAPOR2 | c.1292G>T p.G431V (on ENST00000450689 / NM_001142749.3; = p.G264V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51885230; called by muse, mutect2, varscan2
- EPHA2 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64452461, COSV64453997; called by muse, mutect2, varscan2
- ERCC2 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55539680; called by muse, mutect2, varscan2
- FAM122C | c.257T>C p.M86T | Missense Mutation (SNP) | VAF 124/155 reads (80%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV66194880; called by muse, mutect2, varscan2
- FASTKD3 | c.1873C>G p.Q625E | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52948935; called by muse, mutect2, varscan2
- FBN2 | c.2559A>G p.I853M | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV52502989; called by muse, mutect2, varscan2
- FBXW10 | c.2585C>T p.S862L | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100111477; called by muse, mutect2, varscan2
- FGF13 | c.476T>C p.I159T | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1173095656, COSV59544024; called by muse, mutect2, varscan2
- FKBP5 | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61880777; called by muse, mutect2, varscan2
- FLNC | c.4263C>G p.I1421M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV57952977; called by muse, mutect2, varscan2
- FRMD3 | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV58458508; called by muse, mutect2
- FUZ | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV58241077; called by muse, mutect2, varscan2
- GALE | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52525432; called by muse, mutect2
- GARNL3 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763785641, COSV59224764, COSV59228173; called by muse, mutect2, varscan2
- GASK1B | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.361); catalogued as rs1312017135, COSV56705694, COSV56711036, COSV56712584; called by muse, mutect2, varscan2
- GPLD1 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1390490470, COSV57755437; called by muse, mutect2, varscan2
- GTF2A1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 61/83 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV53336608; called by muse, mutect2, varscan2
- GTF2I | c.1283G>C p.R428T (on ENST00000573035 / NM_032999.4; = p.R387T on NM_001518.5) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as COSV100260093; called by muse, mutect2, varscan2
- GUF1 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV55781931; called by muse, mutect2, varscan2
- H2BC10 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100010408, COSV59952776, COSV59953804; called by muse, mutect2, varscan2
- HSP90AA1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53487929; called by muse, mutect2, varscan2
- IGLV2-8 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 220/521 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs560474360; called by muse, mutect2, varscan2
- IGLV3-27 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs946032332; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1741C>A p.L581I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV61148281; called by muse, mutect2, varscan2
- IQCN | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV66573189; called by muse, mutect2, varscan2
- ISL1 | c.896T>C p.L299S | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV57932939; called by muse, mutect2, varscan2
- ITGA4 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV51998887; called by muse, mutect2, varscan2
- ITPR1 | c.1780A>T p.T594S (on ENST00000354582; = p.T579S on NM_002222.7) | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56974814; called by muse, mutect2, varscan2
- ITSN2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61945079; called by muse, mutect2, varscan2
- KAT6A | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); catalogued as COSV55904493; called by muse, mutect2, varscan2
- KBTBD6 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as COSV65271073; called by muse, mutect2, varscan2
- KCNA6 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.206); catalogued as rs372964376, COSV99769076; called by muse, mutect2, varscan2
- KCNN1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as rs1397119886, COSV55837753; called by muse, mutect2, varscan2
- KLHDC3 | c.458T>G p.F153C | Missense Mutation (SNP) | VAF 74/118 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55063877; called by muse, mutect2, varscan2
- L3MBTL2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.914); catalogued as COSV53432399; called by muse, mutect2, varscan2
- LCMT2 | c.219G>C p.Q73H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.382); catalogued as rs1377533439, COSV59789907; called by muse, mutect2, varscan2
- LIMS1 | c.607C>G p.R203G | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57539765; called by muse, mutect2, varscan2
- LIN28A | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54261167; called by muse, mutect2, varscan2
- LMNA | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 77/110 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as CM0910022, COSV61542252; called by muse, mutect2, varscan2
- LMTK3 | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54310976; called by muse, mutect2, varscan2
- LPIN2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as COSV55238384; called by muse, mutect2, varscan2
- LRRTM3 | c.1333T>C p.Y445H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV63663132; called by muse, mutect2, varscan2
- MALT1 | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61934414; called by muse, mutect2, varscan2
- MAP4K2 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53641711; called by muse, mutect2, varscan2
- MAP4K3 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | catalogued as COSV55712006; called by muse, mutect2, varscan2
- MAPK9 | c.189C>A p.N63K | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58120176; called by muse, mutect2, varscan2
- MBD6 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60765157; called by muse, mutect2, varscan2
- MBD6 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60765160; called by muse, mutect2, varscan2
- MED27 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99406631; called by muse, varscan2
- MEI1 | c.2647C>G p.R883G | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV55901203, COSV55901796, COSV55902853; called by muse, mutect2, varscan2
- MEOX2 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV56294581; called by muse, mutect2, varscan2
- MIB1 | c.848G>C p.G283A | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55088902; called by muse, mutect2, varscan2
- MIGA2 | c.32T>C p.M11T | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV52976310; called by muse, mutect2, varscan2
- MTMR6 | c.1298A>G p.Q433R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1044879824, COSV67807990; called by muse, mutect2, varscan2
- MTSS2 | c.1651A>G p.T551A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV55380344; called by muse, mutect2, varscan2
- MUC2 | c.2068G>C p.E690Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs754841337; called by muse, mutect2, varscan2
- MUC6 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV70137363; called by muse, mutect2, varscan2
- MUS81 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV57378996; called by muse, mutect2, varscan2
- MYH3 | c.1838C>G p.S613C | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV56862797; called by muse, mutect2, varscan2
- N4BP2 | c.5115G>C p.L1705F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746243449, COSV54700425; called by muse, mutect2, varscan2
- NAP1L1 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as COSV53873865; called by mutect2, varscan2
- NAV1 | c.4450G>C p.E1484Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV55215603, COSV55225504; called by muse, mutect2, varscan2
- NCMAP | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV65556287; called by muse, mutect2, varscan2
- NEK10 | c.1981A>G p.I661V | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV58281487; called by muse, mutect2, varscan2
- NFX1 | c.3115C>A p.Q1039K | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV65351268; called by muse, mutect2, varscan2
- NLGN1 | c.923A>T p.Q308L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV64327337; called by muse, mutect2, varscan2
- NOC2L | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV100497885, COSV58986677; called by muse, mutect2, varscan2
- NTRK2 | c.700A>T p.N234Y | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.37); catalogued as COSV52858340; called by muse, mutect2, varscan2
- NXPE3 | c.1193A>G p.K398R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.306); catalogued as COSV56289158; called by muse, mutect2, varscan2
- OBI1 | c.1385C>G p.P462R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV56145039; called by muse, mutect2, varscan2
- OR11H4 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV59559987; called by muse, mutect2, varscan2
- PDIA5 | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV60248120; called by muse, mutect2, varscan2
- PHF20 | c.1419G>A p.M473I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV104410312, COSV59185145; called by muse, mutect2, varscan2
- PHLDB3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs1311047179, COSV52668595; called by muse, mutect2, varscan2
- PLD5 | c.700G>T p.G234C (on ENST00000442594; = p.G172C on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59138637; called by muse, mutect2, varscan2
- PPP1R12A | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99700693; called by muse, mutect2, varscan2
- PRCC | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs1558051442, COSV54855619; called by muse, mutect2, varscan2
- PRDM2 | c.1913A>G p.K638R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as COSV52444423; called by muse, mutect2, varscan2
- PRDX4 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV65025895; called by muse, mutect2, varscan2
- PTCD1 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as rs1422857949; called by muse, mutect2, varscan2
- PTH2 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.119); catalogued as COSV54528078; called by muse, mutect2
- PTPMT1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs1483358313, COSV100442790, COSV100442953, COSV58596904; called by muse, mutect2, varscan2
- RASAL2 | c.359A>G p.Q120R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs1462957650, COSV62711569; called by muse, mutect2, varscan2
- RBM18 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV101313784; called by muse, mutect2, varscan2
- RCC2 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV64905524; called by muse, mutect2, varscan2
- RGMA | c.821C>A p.A274D | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61233434; called by muse, mutect2, varscan2
- RIF1 | c.3103G>T p.V1035L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54614692; called by muse, mutect2, varscan2
- RNF113A | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 205/237 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65097212; called by muse, mutect2, varscan2
- RXYLT1 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as rs373899387; called by muse, mutect2, varscan2
- SACS | c.11362C>T p.R3788C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs931398747, COSV66537203; called by muse, mutect2, varscan2
- SAMD14 | c.1118C>T p.S373F (on ENST00000330175 / NM_001257359.2; = p.S401F on NM_174920.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV50303416; called by muse, mutect2, varscan2
- SDE2 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV55250674; called by muse, mutect2, varscan2
- SDHA | c.1204G>C p.V402L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV53766638; called by muse, mutect2, varscan2
- SEMA3D | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV52390036; called by muse, mutect2, varscan2
- SEMA5A | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770636604, COSV66787951; called by muse, mutect2, varscan2
- SETD2 | c.3835G>A p.G1279R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57433735; called by muse, mutect2, varscan2
- SFN | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.149); catalogued as COSV59433059; called by muse, mutect2
- SH3RF1 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.996); catalogued as COSV52919348; called by muse, mutect2, varscan2
- SH3RF1 | c.2315C>A p.S772Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV52918170, COSV52919354; called by muse, mutect2, varscan2
- SHROOM2 | c.2892A>G p.R964= | Splice Region (SNP) | VAF 27/45 reads (60%) | catalogued as COSV66605441; called by muse, mutect2, varscan2
- SLC27A6 | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV52481479; called by muse, mutect2, varscan2
- SLC29A1 | c.1264G>C p.V422L | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57577720; called by muse, mutect2, varscan2
- SLC2A3 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50000612; called by muse, mutect2, varscan2
- SLC4A5 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.068); catalogued as COSV61026045; called by muse, mutect2, varscan2
- SLC9A7 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV60378924; called by muse, mutect2, varscan2
- SOX5 | c.322A>T p.T108S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58623556; called by muse, mutect2, varscan2
- SPRED2 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62691951; called by muse, mutect2, varscan2
- SSH3 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57383917; called by muse, mutect2, varscan2
- SULT1C4 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT tolerated (0.56); PolyPhen benign (0.045); catalogued as COSV55597539; called by muse, mutect2, varscan2
- SYCP2 | c.3249G>C p.W1083C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.634); catalogued as COSV100698449, COSV62767090, COSV62767134; called by muse, mutect2, varscan2
- SYNE2 | c.2548A>G p.M850V | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs765308380, COSV59944481; called by muse, mutect2, varscan2
- TADA2B | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs1232633836, COSV59508394; called by muse, mutect2, varscan2
- TASOR | c.3986C>G p.T1329R (on ENST00000355628 / NM_001365636.2; = p.T953R on NM_015224.3) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV104399230, COSV58302427; called by muse, mutect2
- TEC | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51913738; called by muse, mutect2, varscan2
- TENT5B | c.1277G>C p.*426Sext*26 | Nonstop Mutation (SNP) | VAF 92/154 reads (60%) | catalogued as COSV100006634; called by muse, mutect2, varscan2
- TFB1M | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV65698564; called by muse, mutect2, varscan2
- THBD | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV65702142; called by muse, mutect2, varscan2
- TIMM17A | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV66170918; called by muse, mutect2, varscan2
- TLR10 | c.1133T>A p.I378N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV58299586; called by muse, mutect2, varscan2
- TLR10 | c.1003A>C p.N335H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV58299595; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV56694992; called by muse, mutect2, varscan2
- TNFRSF25 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs766596661, COSV100556984, COSV61068029; called by muse, mutect2, varscan2
- TP73 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.46); catalogued as COSV60699818; called by muse, mutect2, varscan2
- TRANK1 | c.3052A>G p.I1018V | Missense Mutation (SNP) | VAF 109/200 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV57145293; called by muse, mutect2, varscan2
- TRAPPC10 | c.2666C>G p.P889R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV52376293; called by muse, mutect2, varscan2
- TRIM43 | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 122/229 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV55527814; called by muse, mutect2, varscan2
- TRIM55 | c.1534G>C p.E512Q (on ENST00000315962 / NM_184085.2; = p.*541Sext*18 on NM_033058.3) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV52541691; called by muse, mutect2
- TRPA1 | c.1908A>G p.V636= | Splice Region (SNP) | VAF 13/65 reads (20%) | catalogued as COSV51557858; called by muse, mutect2, varscan2
- TTN | c.45949G>A p.D15317N (on ENST00000591111; = p.D7893N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | PolyPhen benign (0.43); catalogued as COSV100617677, COSV100620430; called by muse, mutect2, varscan2
- UBAP2L | c.1663A>G p.S555G | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1469141333, COSV55170225; called by muse, mutect2, varscan2
- UBN2 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56028878; called by muse, mutect2, varscan2
- UGT2B4 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV59316067; called by muse, mutect2, varscan2
- ULK4 | c.1634A>G p.Q545R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57203535; called by muse, mutect2
- UPK1A | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.974); catalogued as COSV55877809; called by muse, mutect2, varscan2
- USP38 | c.1926T>G p.D642E | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.051); catalogued as COSV61025175; called by muse, mutect2, varscan2
- USP39 | c.579_593del p.P195_K199del | In Frame Del (DEL) | VAF 9/89 reads (10%) | catalogued as COSV60381227; called by mutect2, varscan2
- VAV1 | c.1907G>A p.W636* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100409032; called by muse, mutect2, varscan2
- VPS13B | c.2837T>C p.L946P | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1191190771, COSV62137173; called by muse, mutect2
- VPS13B | c.4400C>T p.S1467L | Missense Mutation (SNP) | VAF 151/174 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs751646100, COSV62137180; called by muse, mutect2, varscan2
- WDFY1 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99239479; called by muse, mutect2, varscan2
- WDR36 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72605126; called by muse, mutect2, varscan2
- XYLB | c.1531C>A p.Q511K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV52912209; called by muse, mutect2, varscan2
- YTHDF2 | c.1717-1G>A p.X573_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV65723000; called by muse, mutect2, varscan2
- ZDHHC7 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs754472871, COSV58212043; called by muse, mutect2, varscan2
- ZFP14 | c.542T>G p.F181C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54201633; called by muse, mutect2, varscan2
- ZFPM2 | c.1841C>A p.A614D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV65872963; called by muse, mutect2, varscan2
- ZHX3 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV58381971; called by muse, mutect2, varscan2
- ZNF202 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.883); catalogued as COSV60246752; called by muse, mutect2, varscan2
- ZNF267 | c.1438A>T p.I480F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV56251439; called by muse, mutect2, varscan2
- ZNF300 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs1223679898, COSV51032888; called by muse, mutect2, varscan2
- ZNF45 | c.933G>C p.K311N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1213035241, COSV54192682; called by muse, mutect2, varscan2
- ZNF513 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52006702; called by muse, mutect2, varscan2
- ZNF594 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV68384949; called by muse, mutect2, varscan2
- ZNF721 | c.1706G>C p.G569A (on ENST00000338977; = p.G581A on NM_133474.4) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV59090515, COSV59092693, COSV59093580; called by muse, mutect2, varscan2
- ZNF99 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs781473162, COSV68055265; called by muse, varscan2
- ABHD18 | c.424T>A p.L142M (on ENST00000398965 / NM_001039717.2; = p.L15M on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTL8 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 32/50 reads (64%) | called by muse, mutect2, varscan2
- ANO10 | c.1916A>C p.Q639P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- ARVCF | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 63/158 reads (40%) | called by muse, mutect2, varscan2
- CSTF2T | c.298_300del p.E100del | In Frame Del (DEL) | VAF 18/117 reads (15%) | called by pindel, varscan2
- DUSP14 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGN1 | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); called by muse, mutect2
- IGKV1D-17 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 134/275 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- IKZF3 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 1138/1254 reads (91%) | called by muse, mutect2, varscan2
- KIDINS220 | c.2280_2293del p.D760Efs*16 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, varscan2
- KMT2A | c.11779_11780del p.V3927Hfs*6 | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | called by mutect2, pindel, varscan2
- PRDM9 | c.1488A>C p.E496D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.475); called by muse, mutect2
- SLC22A1 | c.1077_1091del p.L360_L364del | In Frame Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- TMC7 | c.2107-1_2109del p.X703_splice | Splice Site (DEL) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- TP53AIP1 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2
- UGT1A9 | c.206C>A p.S69* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- ABCC12 | c.3066C>T p.L1022= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV60912686; called by muse, mutect2, varscan2
- ACIN1 | c.454C>T p.L152= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV52974577; called by muse, mutect2
- ADD1 | c.1818G>T p.A606= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV53267305; called by muse, mutect2, varscan2
- ADGRG2 | c.2703G>C p.L901= (on ENST00000379869 / NM_001079858.3; = p.L898= on NM_005756.4) | Silent (SNP) | VAF 56/76 reads (74%) | catalogued as COSV61338217; called by muse, mutect2, varscan2
- ADGRG4 | c.5850G>C p.G1950= | Silent (SNP) | VAF 87/106 reads (82%) | catalogued as COSV54952331; called by muse, mutect2, varscan2
- ADH1B | c.423C>T p.F141= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs372727625; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1872G>A p.V624= | Silent (SNP) | VAF 8/45 reads (18%) | called by mutect2, varscan2
- ANKRD34A | c.834G>T p.L278= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV60160510; called by muse, mutect2, varscan2
- ARHGAP21 | c.4131C>T p.V1377= | Silent (SNP) | VAF 83/172 reads (48%) | catalogued as COSV57604042; called by muse, mutect2, varscan2
- ARHGAP5 | c.3066T>C p.H1022= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV61534604; called by muse, mutect2, varscan2
- ASAP3 | c.315C>T p.F105= | Silent (SNP) | VAF 93/142 reads (65%) | catalogued as COSV60873704, COSV60875567; called by muse, mutect2, varscan2
- BTBD1 | c.672C>G p.L224= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV55602286; called by muse, mutect2, varscan2
- CBX4 | c.759C>G p.V253= | Silent (SNP) | VAF 153/334 reads (46%) | catalogued as rs567650384, COSV53965035; called by muse, mutect2, varscan2
- CDC25B | c.600G>A p.K200= (on ENST00000245960 / NM_021873.3; = p.K186= on NM_004358.4) | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV55655346; called by muse, mutect2
- CDHR1 | c.2136C>T p.V712= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs1250877654, COSV60560735; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5667C>T p.S1889= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1227011096, COSV62573150; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4764C>T p.F1588= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV62573156, COSV62574457; called by muse, mutect2, varscan2
- CHAD | c.549G>A p.L183= | Silent (SNP) | VAF 14/159 reads (9%) | catalogued as rs1242636525, COSV51971804; called by muse, mutect2
- COL4A2 | c.4731C>G p.P1577= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV64626480, COSV64634335; called by muse, mutect2, varscan2
- COL6A3 | c.3411C>T p.I1137= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs368285658, COSV99796899; ClinVar: likely benign; called by muse, mutect2, varscan2
- COQ8A | c.390C>T p.F130= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs1268591125, COSV64656896, COSV64657042; called by muse, mutect2, varscan2
- CTNNA2 | c.1236G>A p.K412= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs768539099, COSV58142741; called by muse, mutect2, varscan2
- CYP24A1 | c.1326G>A p.Q442= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV53773395; called by muse, mutect2, varscan2
- DCAF6 | c.84G>A p.R28= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV54796491; called by muse, mutect2, varscan2
- DHX33 | c.285C>T p.L95= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV50147195; called by muse, mutect2, varscan2
- DISP2 | c.1794C>T p.L598= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV51117894; called by mutect2, varscan2
- DNAH1 | c.6234C>T p.F2078= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1314789263, COSV70227498; called by muse, mutect2, varscan2
- DNAH14 | c.789A>G p.L263= (on ENST00000445597; = p.L136= on NM_144989.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV64780869; called by muse, mutect2, varscan2
- DNAH7 | c.969C>T p.A323= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs1362935266, COSV56757285; called by muse, mutect2, varscan2
- DNAJB6 | c.258A>G p.P86= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as rs754329370, COSV51094752; called by muse, mutect2, varscan2
- DNAJC30 | c.375C>T p.V125= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV56094517; called by muse, mutect2, varscan2
- DNASE1L3 | c.870C>T p.S290= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV59155478; called by muse, mutect2, varscan2
- DOP1B | c.1968C>T p.S656= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs749234893, COSV67692658; called by muse, mutect2, varscan2
- EFCAB14 | c.315C>T p.L105= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1314096116, COSV64238548; called by muse, mutect2
- EIF4G1 | c.1599C>T p.A533= (on ENST00000346169 / NM_198241.3; = p.A337= on NM_004953.5) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV59988823; called by muse, mutect2, varscan2
- ESRP2 | c.135G>C p.L45= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV52172688, COSV52176525; called by muse, mutect2, varscan2
- F12 | c.1164C>T p.A388= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs561975736, COSV53690729; called by muse, mutect2, varscan2
- F12 | c.735C>T p.A245= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV53690739; called by muse, mutect2
- F5 | c.1545C>T p.I515= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs886045551, COSV63122274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMR1 | c.876A>G p.L292= | Silent (SNP) | VAF 32/44 reads (73%) | catalogued as COSV54422670; called by muse, mutect2, varscan2
- FUZ | c.918G>A p.L306= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV58241066; called by muse, mutect2, varscan2
- GOLGB1 | c.6133C>T p.L2045= | Silent (SNP) | VAF 58/83 reads (70%) | catalogued as COSV61463454; called by muse, mutect2, varscan2
- GPI | c.1050G>T p.A350= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs780075559, COSV62893516, COSV62893635; called by muse, mutect2, varscan2
- GPLD1 | c.2406C>T p.S802= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as COSV57755430; called by muse, mutect2
- GPR18 | c.33C>G p.V11= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV61621044; called by muse, mutect2, varscan2
- GRAMD1A | c.990C>T p.T330= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV58766397; called by muse, mutect2, varscan2
- GRM8 | c.2541G>A p.Q847= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100285601, COSV58813920; called by muse, mutect2, varscan2
- GSX2 | c.636G>T p.T212= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV58842576; called by muse, mutect2, varscan2
- HERC2 | c.6114G>A p.Q2038= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs759933701, COSV55311166; called by muse, mutect2, varscan2
- HSPG2 | c.9876C>T p.I3292= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV65932919; called by muse, mutect2, varscan2
- IHH | c.1011A>C p.T337= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV55392932; called by muse, mutect2, varscan2
- ITGA3 | c.1791C>T p.L597= | Silent (SNP) | VAF 33/215 reads (15%) | catalogued as COSV50307452; called by muse, mutect2, varscan2
- ITGA7 | c.1476T>C p.D492= (on ENST00000555728; = p.D448= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs1251329020, COSV57693382; called by muse, mutect2, varscan2
- ITPKC | c.330G>A p.K110= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV54573908; called by muse, mutect2, varscan2
- KIF21B | c.3735G>A p.R1245= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1296422999, COSV59754717; called by muse, mutect2, varscan2
- KRT2 | c.1347G>C p.L449= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV59009640; called by muse, mutect2, varscan2
- LEPR | c.3378T>C p.N1126= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV62746551; called by muse, mutect2, varscan2
- LRP1B | c.24A>G p.L8= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1161528976, COSV101257585; called by muse, mutect2, varscan2
- LRP4 | c.615C>T p.L205= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs1192920799, COSV66134883; called by muse, mutect2, varscan2
- MAP3K15 | c.3249G>A p.S1083= | Silent (SNP) | VAF 46/60 reads (77%) | catalogued as rs1237428910, COSV58826457; called by muse, mutect2, varscan2
- MED27 | c.63C>T p.I21= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs373095490; called by muse, mutect2, varscan2
- MUC6 | c.1575C>T p.F525= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs764283665, COSV70137377; called by muse, mutect2, varscan2
- MYO9B | c.5787G>A p.E1929= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1568305188, COSV55727334; called by muse, mutect2, varscan2
- NIF3L1 | c.348T>A p.A116= (on ENST00000409020 / NM_001369444.1; = p.A89= on NM_021824.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV53768880; called by muse, mutect2, varscan2
- NUP210 | c.4842G>A p.Q1614= | Silent (SNP) | VAF 167/274 reads (61%) | catalogued as rs1298226573, COSV54404311; called by muse, mutect2, varscan2
- OR2L3 | c.501T>C p.Y167= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2
- OR2L8 | c.501T>C p.Y167= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV61726097; called by muse, mutect2, varscan2
- PARVA | c.552C>T p.A184= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as COSV58513425; called by muse, mutect2, varscan2
- PLXNB1 | c.1413G>A p.Q471= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV56488017; called by muse, mutect2, varscan2
- PLXNB3 | c.5370C>T p.F1790= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as COSV62796256; called by muse, mutect2, varscan2
- PRPF4B | c.2793C>T p.Y931= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV61783710; called by muse, mutect2, varscan2
- REG1B | c.423T>G p.T141= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as COSV59304928; called by muse, mutect2, varscan2
- RREB1 | c.444G>A p.E148= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV58555564; called by muse, mutect2, varscan2
- SCFD2 | c.669C>T p.L223= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV66370082; called by muse, mutect2, varscan2
- SMAGP | c.261C>A p.A87= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV66312904; called by muse, mutect2, varscan2
- SNX19 | c.207C>T p.L69= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs775388355, COSV56284693, COSV99773767; called by muse, mutect2, varscan2
- STAP2 | c.15G>A p.L5= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV53656399; called by muse, mutect2, varscan2
- STH | c.144C>T p.L48= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV52238618; called by muse, mutect2
- TACC2 | c.3759G>A p.V1253= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as rs759701337, COSV57746261; called by muse, mutect2, varscan2
- TCF25 | c.642C>T p.P214= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1433790758, COSV54525693; called by muse, mutect2, varscan2
- TMCC3 | c.1167G>A p.K389= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV54153080; called by muse, mutect2, varscan2
- TMCO4 | c.48G>A p.L16= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV53871145; called by muse, mutect2, varscan2
- TMEM132E | c.2094C>T p.T698= (on ENST00000321639; = p.T788= on NM_001304438.2) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV58695623; called by muse, mutect2, varscan2
- TMEM154 | c.207G>T p.P69= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs370355996, COSV58590194; called by muse, mutect2, varscan2
- UFD1 | c.150C>T p.P50= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV54244289; called by muse, mutect2, varscan2
- XKR8 | c.483C>T p.Y161= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs754797378; called by muse, mutect2, varscan2
- XRCC3 | c.123C>T p.L41= | Silent (SNP) | VAF 23/32 reads (72%) | catalogued as COSV61398582; called by muse, mutect2, varscan2
- ZMYND10 | c.1074G>A p.Q358= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as COSV51600871; called by muse, mutect2, varscan2
- ZNF138 | c.675T>C p.C225= (on ENST00000307355 / NM_001367572.1; = p.C199= on NM_006524.4) | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV56464420; called by muse, mutect2, varscan2
- ZNF594 | c.462A>C p.P154= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV68384955; called by muse, mutect2, varscan2
- C12orf77 | n.244C>T | RNA (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- CHI3L1 | c.-2G>A | 5'UTR (SNP) | VAF 30/83 reads (36%) | catalogued as rs985632196, COSV99703984; called by muse, mutect2, varscan2
- DENND10P1 | n.560G>A | RNA (SNP) | VAF 88/105 reads (84%) | called by muse, mutect2, varscan2
- DLG4 | chr17:7218251 G>C | 5'Flank (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- DPM3 | c.-31-11C>G | Intron (SNP) | VAF 70/79 reads (89%) | catalogued as COSV57596450; called by muse, mutect2, varscan2
- FAM169B | n.554G>A | RNA (SNP) | VAF 15/21 reads (71%) | catalogued as COSV60568276; called by muse, mutect2, varscan2
- PSMD7 | c.-1G>A | 5'UTR (SNP) | VAF 17/33 reads (52%) | catalogued as rs1417572433, COSV99542725, COSV99542871; called by muse, mutect2, varscan2
- RGS3 | c.3081-285T>C | Intron (SNP) | VAF 33/147 reads (22%) | catalogued as COSV59514113; called by muse, mutect2, varscan2
- SPTB | c.6345+14C>T | Intron (SNP) | VAF 138/178 reads (78%) | catalogued as rs375155686; called by muse, mutect2, varscan2
